Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A1ZH, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A1ZH-06A (Metastatic).

Prof. Dr. med.
Direktor der

100-0-3

Melanoma, NOS 8720/3

Site: lymph node, NOS C77.9

for 7/24/11

Patient: Xxxx
geb. ** * *

Datum:

F

Translation of pathology report F

Sample

Gross Pathology

Cryofixed specimen with a weight of

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 80 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine. Some apoptotic cells are present. There is a high nucleo/cytoplasmatic ratio. The mitotic count is 5 mitoses per square millimetre. The tumor cells have a middle sized cytoplasm. The tumor shows a sheet like growth pattern. Lymphocytic infiltrates compound approx. 3 percent of the tissue cells. Melanophages are present.

Diagnosis: Parts of a malignat tumor, consistent with a metastasis of a melanoma.

Dr.

CRCF Site = lymph node

Primary Tumor Site Discrepancy (Not stated on path)		
ICD-10 Discrepancy		

Source: NCI Genomic Data Commons file 8031b18d-c917-4a24-9227-4d027342bd0a (TCGA-FS-A1ZH.8DAD99A6-254F-4280-9CA8-E1D9F896F77C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).